Somatic mutation profile of tumor specimen TCGA-DD-AACE-01A (aliquot TCGA-DD-AACE-01A-11D-A40R-10) from TCGA case TCGA-DD-AACE, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 62.2 years (22,727 days).
Specimen TCGA-DD-AACE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 18a68eff-314a-4204-9c35-9e20d8dce589.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AACE-10A (Blood Derived Normal), aliquot TCGA-DD-AACE-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/11304577-63bb-42b4-9c4f-c1a70d2a7685

The open-access MAF lists 80 somatic variants for this specimen: 60 protein-altering or splice-affecting, 18 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 18, Frame Shift Del 3, Nonsense Mutation 2, 3'UTR 2, Splice Region 1, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC12 | c.686A>G p.Y229C | Missense Mutation (SNP) | VAF 45/166 reads (27%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.886); catalogued as COSV100253357; called by muse, mutect2, varscan2
- ADGRL3 | c.3549G>T p.Q1183H (on ENST00000506720 / NM_001322402.2; = p.Q1115H on NM_015236.6) | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV101547415, COSV99072528; called by muse, mutect2, varscan2
- AGT | c.1388C>T p.A463V | Missense Mutation (SNP) | VAF 95/246 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.212); catalogued as rs769416248, COSV100794498; called by muse, mutect2, varscan2
- AHNAK2 | c.6110G>A p.S2037N | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.85); catalogued as COSV100319162; called by muse, mutect2
- CHRNA7 | c.85C>A p.L29I | Missense Mutation (SNP) | VAF 52/81 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199819119, COSV100181816; called by muse, mutect2, varscan2
- CLNK | c.283G>C p.E95Q | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.382); catalogued as COSV99905987; called by muse, mutect2, varscan2
- CNTN3 | c.2548G>A p.E850K | Missense Mutation (SNP) | VAF 68/121 reads (56%) | SIFT tolerated (0.17); PolyPhen benign (0.099); catalogued as COSV55170776; called by muse, mutect2, varscan2
- COL16A1 | c.3492G>A p.P1164= | Splice Region (SNP) | VAF 18/60 reads (30%) | catalogued as rs995290122, COSV99595629; called by muse, mutect2, varscan2
- COL4A1 | c.3656G>T p.G1219V | Missense Mutation (SNP) | VAF 47/185 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101011627; called by muse, mutect2
- COL4A3 | c.1936G>T p.G646* | Nonsense Mutation (SNP) | VAF 27/76 reads (36%) | catalogued as COSV101170596; called by muse, mutect2, varscan2
- CUBN | c.298A>G p.I100V | Missense Mutation (SNP) | VAF 44/78 reads (56%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs765554733, COSV100910696; called by muse, mutect2, varscan2
- DHX8 | c.2197C>A p.P733T | Missense Mutation (SNP) | VAF 103/163 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV99292676; called by muse, mutect2, varscan2
- EDARADD | c.166G>C p.E56Q (on ENST00000334232 / NM_145861.4; = p.E46Q on NM_080738.4) | Missense Mutation (SNP) | VAF 62/404 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.214); catalogued as COSV100513191; called by muse, mutect2
- EFTUD2 | c.659G>A p.R220H | Missense Mutation (SNP) | VAF 66/103 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs765588398, COSV68183025; called by muse, mutect2, varscan2
- ERMAP | c.269T>A p.L90Q | Missense Mutation (SNP) | VAF 71/130 reads (55%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV100072420; called by muse, mutect2, varscan2
- F5 | c.29T>G p.V10G | Missense Mutation (SNP) | VAF 54/83 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as COSV99741288; called by muse, mutect2, varscan2
- FAM53A | c.577G>T p.G193C | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100357310; called by muse, mutect2, varscan2
- FOXG1 | c.931T>A p.S311T | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as COSV100487114; called by muse, mutect2, varscan2
- FZR1 | c.778G>A p.A260T | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as rs754635012, COSV100553401; called by muse, mutect2
- HCN1 | c.1729C>A p.P577T | Missense Mutation (SNP) | VAF 41/144 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100302620; called by muse, mutect2, varscan2
- HCN1 | c.572T>C p.I191T | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.145); catalogued as COSV100302621; called by muse, mutect2, varscan2
- INTS3 | c.3104C>T p.S1035F | Missense Mutation (SNP) | VAF 139/179 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99670213; called by muse, mutect2, varscan2
- ITIH3 | c.1214C>A p.P405H | Missense Mutation (SNP) | VAF 29/153 reads (19%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.796); catalogued as COSV101407172; called by muse, mutect2, varscan2
- KCNN3 | c.380G>A p.G127D | Missense Mutation (SNP) | VAF 47/254 reads (19%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (1); catalogued as rs1322174628, COSV99679374; called by muse, mutect2, varscan2
- KIF5C | c.592A>G p.M198V | Missense Mutation (SNP) | VAF 60/145 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV101276219; called by muse, mutect2, varscan2
- KLHL10 | c.317C>T p.P106L | Missense Mutation (SNP) | VAF 50/224 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.058); catalogued as rs1021250962, COSV99509703; called by muse, mutect2, varscan2
- MAMDC2 | c.311T>A p.M104K | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.05); catalogued as COSV101015907; called by muse, mutect2, varscan2
- MARVELD3 | c.187C>G p.Q63E | Missense Mutation (SNP) | VAF 52/211 reads (25%) | SIFT tolerated (0.89); PolyPhen benign (0.001); catalogued as COSV99194882; called by muse, mutect2, varscan2
- NRAS | c.112-1G>A p.X38_splice | Splice Site (SNP) | VAF 37/57 reads (65%) | catalogued as COSV54759501; called by muse, mutect2, varscan2
- ODC1 | c.1267C>T p.P423S | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV99301408; called by muse, mutect2, varscan2
- OR5H14 | c.275T>A p.I92K | Missense Mutation (SNP) | VAF 52/193 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as COSV101454329; called by muse, mutect2, varscan2
- OSBPL7 | c.2087G>T p.R696L | Missense Mutation (SNP) | VAF 51/84 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.695); catalogued as COSV99137147; called by muse, mutect2, varscan2
- PCDHGC3 | c.1330C>T p.R444C | Missense Mutation (SNP) | VAF 72/120 reads (60%) | SIFT tolerated (0.17); PolyPhen benign (0.417); catalogued as COSV52751363; called by muse, mutect2, varscan2
- PGLS | c.293A>G p.H98R | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.474); catalogued as COSV99395797; called by muse, mutect2, varscan2
- PHF23 | c.1109T>G p.I370S | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99138931; called by muse, mutect2, varscan2
- PIK3R1 | c.703C>T p.Q235* | Nonsense Mutation (SNP) | VAF 85/150 reads (57%) | catalogued as COSV99160732; called by muse, mutect2, varscan2
- PITPNM2 | c.2563G>A p.A855T | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs1406337308, COSV99759784; called by muse, mutect2, varscan2
- PON3 | c.372T>A p.N124K | Missense Mutation (SNP) | VAF 53/131 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV99672768; called by muse, mutect2, varscan2
- POPDC2 | c.868T>A p.C290S | Missense Mutation (SNP) | VAF 85/177 reads (48%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV99951199; called by muse, mutect2, varscan2
- POTEF | c.664G>A p.A222T | Missense Mutation (SNP) | VAF 63/235 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.424); catalogued as COSV100665415; called by muse, mutect2, varscan2
- PRKDC | c.1445T>A p.V482E | Missense Mutation (SNP) | VAF 58/116 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV100043259; called by muse, mutect2, varscan2
- RSAD1 | c.685T>G p.S229A | Missense Mutation (SNP) | VAF 77/133 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV51957270, COSV99364422; called by muse, mutect2, varscan2
- SIAH3 | c.130C>A p.L44I | Missense Mutation (SNP) | VAF 76/139 reads (55%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.259); catalogued as COSV68551296; called by muse, varscan2
- SIGLEC1 | c.1690G>T p.A564S | Missense Mutation (SNP) | VAF 78/144 reads (54%) | SIFT tolerated (0.23); PolyPhen benign (0.286); catalogued as rs756452334, COSV52474008, COSV99171436; called by muse, mutect2, varscan2
- SLC22A2 | c.470A>G p.N157S | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.302); catalogued as COSV100871078; called by muse, mutect2, varscan2
- SLC4A8 | c.1311T>A p.H437Q | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT tolerated (0.41); PolyPhen benign (0.067); catalogued as COSV100177643; called by muse, mutect2, varscan2
- SMG7 | c.1415G>A p.R472K | Missense Mutation (SNP) | VAF 73/497 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.024); catalogued as COSV100750604; called by muse, mutect2, varscan2
- TCERG1 | c.3121G>T p.D1041Y | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV99695342; called by muse, mutect2, varscan2
- TCHHL1 | c.2660A>G p.H887R | Missense Mutation (SNP) | VAF 68/199 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV100916630; called by muse, mutect2, varscan2
- TCOF1 | c.2462A>G p.Q821R (on ENST00000377797 / NM_001135243.1; = p.Q744R on NM_000356.4) | Missense Mutation (SNP) | VAF 80/138 reads (58%) | SIFT tolerated (0.54); PolyPhen benign (0.07); catalogued as COSV100078460; called by muse, mutect2, varscan2
- TP53 | c.983del p.F328Sfs*17 | Frame Shift Del (DEL) | VAF 37/75 reads (49%) | catalogued as COSV52730478; called by mutect2, pindel, varscan2
- TREM1 | c.314T>C p.V105A | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.312); catalogued as COSV99776356; called by muse, mutect2
- TTN | c.36478A>T p.S12160C (on ENST00000591111; = p.S4736C on NM_003319.4) | Missense Mutation (SNP) | VAF 27/69 reads (39%) | PolyPhen possibly damaging (0.614); catalogued as COSV100633093, COSV59889210; called by muse, mutect2, varscan2
- UNC79 | c.7732C>T p.R2578C (on ENST00000393151 / NM_001346218.2; = p.R2401C on NM_020818.5) | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99828704; called by muse, mutect2, varscan2
- ZNF282 | c.269A>T p.Q90L | Missense Mutation (SNP) | VAF 66/131 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as COSV100021902; called by muse, mutect2, varscan2
- ZNF696 | c.19C>G p.P7A | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.011); catalogued as COSV100350673; called by muse, mutect2, varscan2
- ERBB4 | c.2204del p.G735Vfs*10 | Frame Shift Del (DEL) | VAF 6/49 reads (12%) | called by mutect2, pindel, varscan2
- INTS7 | c.2419G>C p.A807P | Missense Mutation (SNP) | VAF 5/126 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- TMEM165 | c.715_717del p.Q239del | In Frame Del (DEL) | VAF 50/149 reads (34%) | called by mutect2, pindel, varscan2
- WNK3 | c.4013_4014del p.Q1338Rfs*25 | Frame Shift Del (DEL) | VAF 45/76 reads (59%) | called by mutect2, pindel, varscan2
- A4GNT | c.210C>T p.S70= | Silent (SNP) | VAF 105/213 reads (49%) | catalogued as rs374392631, COSV52629894; called by muse, mutect2, varscan2
- ABCA9 | c.4653G>A p.L1551= | Silent (SNP) | VAF 28/110 reads (25%) | catalogued as rs1390355465, COSV100383579; called by muse, mutect2, varscan2
- CELSR3 | c.1509C>T p.R503= | Silent (SNP) | VAF 32/127 reads (25%) | catalogued as COSV99375225; called by muse, mutect2, varscan2
- CHAF1A | c.1026G>A p.E342= | Silent (SNP) | VAF 20/71 reads (28%) | catalogued as COSV100011518; called by muse, mutect2, varscan2
- ECHS1 | c.546T>A p.A182= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as COSV100881931; called by muse, mutect2, varscan2
- EPHB4 | c.693T>A p.P231= | Silent (SNP) | VAF 56/134 reads (42%) | catalogued as COSV100639683; called by muse, mutect2, varscan2
- EXTL3 | c.384G>T p.L128= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as COSV99594403; called by muse, mutect2, varscan2
- FRAS1 | c.5454T>C p.D1818= | Silent (SNP) | VAF 23/50 reads (46%) | catalogued as COSV53603098, COSV99356204; called by muse, mutect2, varscan2
- GCC1 | c.51G>A p.L17= | Silent (SNP) | VAF 47/96 reads (49%) | catalogued as COSV99133979; called by muse, mutect2, varscan2
- HK1 | c.2391G>A p.L797= | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as COSV100068144; called by muse, mutect2, varscan2
- HK2 | c.2007C>T p.D669= | Silent (SNP) | VAF 24/67 reads (36%) | catalogued as COSV99309657; called by muse, mutect2, varscan2
- MYO1G | c.2040G>T p.L680= | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as COSV99349197; called by muse, mutect2, varscan2
- NID2 | c.1233A>G p.P411= | Silent (SNP) | VAF 33/97 reads (34%) | catalogued as COSV99357371; called by muse, mutect2, varscan2
- PROSER2 | c.1023G>A p.L341= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV99509047; called by muse, mutect2
- TICRR | c.2487A>G p.S829= | Silent (SNP) | VAF 31/95 reads (33%) | catalogued as COSV99180465; called by muse, mutect2, varscan2
- TMEM144 | c.855A>C p.A285= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV99647033; called by muse, mutect2
- ZDBF2 | c.5556A>G p.E1852= | Silent (SNP) | VAF 40/101 reads (40%) | catalogued as COSV100985628; called by muse, mutect2, varscan2
- ZNF627 | c.384A>G p.P128= | Silent (SNP) | VAF 65/164 reads (40%) | catalogued as COSV100741536; called by muse, mutect2, varscan2
- B4GALNT1 | c.*1063C>A | 3'UTR (SNP) | VAF 15/39 reads (38%) | catalogued as COSV100247349; called by muse, mutect2, varscan2
- ZNF444 | c.*1C>T | 3'UTR (SNP) | VAF 4/22 reads (18%) | catalogued as COSV100442775; called by muse, mutect2, varscan2
